Somatic mutation profile of tumor specimen TCGA-CQ-5331-01A (aliquot TCGA-CQ-5331-01A-02D-1870-08) from TCGA case TCGA-CQ-5331, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Tumor grade: G2; Age at diagnosis: 73.7 years (26,901 days).
Specimen TCGA-CQ-5331-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb493b8b-850a-4397-8ebc-611e9c4890b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5331-10A (Blood Derived Normal), aliquot TCGA-CQ-5331-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c461edc-73cd-482b-92a4-bdf57993fae7

The open-access MAF lists 153 somatic variants for this specimen: 116 protein-altering or splice-affecting, 32 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 32, Nonsense Mutation 7, Intron 4, Splice Site 3, Splice Region 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.920-1G>C p.X307_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | hotspot (GDC flag); catalogued as rs587781702, CS0910927, CS114009, COSV52664150, COSV52690279, COSV52737535; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as rs144369247; called by muse, mutect2
- ACP3 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313535, COSV60485369; called by muse, mutect2
- ACSS1 | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 41/256 reads (16%) | catalogued as COSV100053994; called by muse, mutect2, varscan2
- ADAM22 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55968532; called by muse, mutect2, varscan2
- AMER1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100366946; called by muse, mutect2, varscan2
- AOX1 | c.1856G>C p.R619T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV101022208; called by muse, mutect2, varscan2
- APOH | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs751154716, COSV52773441; called by muse, mutect2, varscan2
- ARHGAP28 | c.1652C>G p.S551C (on ENST00000383472 / NM_001366230.1; = p.S392C on NM_001010000.3) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99151334; called by muse, mutect2, varscan2
- ARPC2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99826859; called by muse, mutect2, varscan2
- ATP11A | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1009070726, COSV99369776; called by muse, mutect2, varscan2
- AXIN2 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100196897; called by muse, mutect2, varscan2
- BEGAIN | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100767021; called by muse, mutect2, varscan2
- BICD1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as COSV55674896; called by muse, mutect2
- BORA | c.1810G>A p.E604K (on ENST00000613797; = p.E529K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); catalogued as COSV100899972; called by muse, mutect2
- C1GALT1 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99777638; called by muse, mutect2, varscan2
- CACNA1S | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100755325; called by muse, mutect2, varscan2
- CAMKK1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50124944; called by muse, mutect2
- CASP8 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV51848261; called by muse, mutect2, varscan2
- CCDC66 | c.886G>A p.E296K (on ENST00000394672 / NM_001353147.1; = p.E262K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV100414297; called by muse, mutect2, varscan2
- CDCA5 | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99298005; called by muse, mutect2
- CNOT4 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100212131; called by muse, mutect2, varscan2
- CPEB1 | c.1695G>C p.Q565H (on ENST00000617958; = p.Q500H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99917965; called by muse, mutect2
- CREBRF | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV99756315; called by muse, mutect2, varscan2
- CWC27 | c.1043-1G>C p.X348_splice | Splice Site (SNP) | VAF 8/111 reads (7%) | catalogued as COSV101126592; called by muse, mutect2
- CWH43 | c.1988G>C p.R663T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as COSV56937724, COSV99893438, COSV99893963; called by muse, mutect2
- DAAM1 | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100658632; called by muse, mutect2
- DCAF16 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs199782348, COSV101200476; called by muse, mutect2, varscan2
- DISP2 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV99140478; called by muse, mutect2, varscan2
- DMD | c.6612G>C p.K2204N | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV58954341; called by muse, mutect2
- DNAH1 | c.4569G>A p.L1523= | Splice Region (SNP) | VAF 23/130 reads (18%) | catalogued as COSV101326905; called by muse, mutect2, varscan2
- DNAH11 | c.13225G>A p.D4409N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100180543; called by muse, mutect2, varscan2
- DPYSL4 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs752975196, COSV58306050; called by muse, mutect2, varscan2
- DRC7 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs116219187, COSV100395500; called by muse, mutect2, varscan2
- DYRK2 | c.1490G>A p.G497E (on ENST00000344096 / NM_006482.3; = p.G424E on NM_003583.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as COSV100165385; called by muse, mutect2, varscan2
- E2F5 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809707; called by muse, mutect2, varscan2
- EDF1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99808239; called by muse, mutect2, varscan2
- EP300 | c.3611G>A p.C1204Y | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54340861, COSV99609599; called by muse, varscan2
- EYA1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.067); catalogued as COSV58163331; called by muse, mutect2, varscan2
- FAM124A | c.872G>C p.R291T (on ENST00000322475 / NM_001242312.2; = p.R327T on NM_145019.4) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as COSV99696439; called by muse, mutect2, varscan2
- FZD6 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100708482; called by muse, mutect2, varscan2
- GNPTAB | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as rs1430287278, COSV73418409; called by muse, mutect2, varscan2
- GP5 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99757570; called by muse, mutect2, varscan2
- GPR149 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.721); catalogued as rs1218259890, COSV67670971; called by muse, mutect2, varscan2
- GPR39 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375756316; called by muse, mutect2, varscan2
- HAUS8 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99505432, COSV99505488; called by muse, mutect2, varscan2
- ICAM2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs762486972, COSV56743163; called by muse, mutect2, varscan2
- IDO1 | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs369075008, COSV99503583; called by muse, mutect2, varscan2
- ING1 | c.1232T>G p.L411R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100312336; called by muse, mutect2, varscan2
- IQGAP1 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99185312; called by muse, mutect2
- KAT6B | c.4147G>C p.D1383H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.121); catalogued as COSV99768917; called by muse, mutect2
- KIF3A | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV101109488; called by muse, mutect2, varscan2
- KRT74 | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV99977606, COSV99977670; called by muse, mutect2, varscan2
- LCMT2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2
- MAGEC1 | c.2992C>A p.R998S | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.078); catalogued as COSV53575613, COSV99596397; called by muse, mutect2
- MAP1A | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100289143, COSV100289259; called by muse, mutect2
- MED12 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100379663, COSV61352274; called by muse, mutect2
- MFSD4B | c.67G>A p.E23K (on ENST00000368847; = p.G118E on NM_153369.4) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV100920610; called by muse, mutect2, varscan2
- MKS1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV58302801; called by muse, mutect2, varscan2
- MST1R | c.3883G>A p.D1295N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56567924, COSV99619528; called by muse, mutect2, varscan2
- MTMR7 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779561293, COSV99472705; called by muse, mutect2, varscan2
- NCOR1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.684); catalogued as COSV99251777; called by muse, mutect2
- NEB | c.16813G>T p.A5605S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51177020, COSV99427165; called by muse, mutect2
- NMUR1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs753654709, COSV59404275; called by muse, mutect2, varscan2
- OBSCN | c.3629C>G p.S1210* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | catalogued as COSV99472314; called by muse, mutect2, varscan2
- PCDHA10 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs1168742927, COSV56474773, COSV56522919; called by muse, mutect2, varscan2
- PDCL3 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.049); catalogued as COSV99959684, COSV99959735; called by muse, mutect2, varscan2
- PKHD1 | c.9591G>C p.Q3197H | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs1421251307, COSV100582391; called by muse, mutect2, varscan2
- PKHD1 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM054817, COSV100584365, COSV61861027; called by muse, mutect2, varscan2
- PLOD1 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52140498; called by muse, mutect2, varscan2
- PRUNE2 | c.7829C>T p.S2610F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100945060; called by muse, mutect2, varscan2
- R3HDM2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as rs1266893787, COSV100715517; called by muse, mutect2, varscan2
- RGS7 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV58538656; called by muse, mutect2, varscan2
- RIMKLB | c.1113C>G p.F371L | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV100224039, COSV55240328; called by muse, mutect2, varscan2
- ROBO2 | c.3516G>C p.L1172F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59923595; called by muse, mutect2, varscan2
- RPS6KA5 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100003107, COSV100003306; called by muse, mutect2, varscan2
- RSF1 | c.2183G>T p.R728M | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100407806; called by muse, mutect2, varscan2
- RYR1 | c.3509C>G p.S1170C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100616792; called by muse, mutect2
- SCLT1 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99828440; called by muse, mutect2
- SNRNP70 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55506160, COSV99672437; called by muse, mutect2, varscan2
- SOCS5 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100125453; called by muse, mutect2, varscan2
- SPAG8 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV99428162; called by muse, mutect2, varscan2
- SPINT1 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV100689194; called by muse, mutect2, varscan2
- STK38L | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV101198818; called by muse, mutect2, varscan2
- SUPV3L1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | catalogued as COSV100669862; called by muse, mutect2, varscan2
- SVEP1 | c.7021G>T p.E2341* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99929643; called by muse, mutect2, varscan2
- SYNCRIP | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100784317; called by muse, mutect2, varscan2
- SYPL1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99163465; called by muse, varscan2
- TARBP1 | c.4462G>T p.G1488W | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242025; called by muse, mutect2, varscan2
- TBC1D25 | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100952217; called by muse, mutect2
- TG | c.570G>C p.M190I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99602854; called by muse, mutect2, varscan2
- THEG | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100700644, COSV61072756; called by muse, mutect2, varscan2
- TMED6 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV99651664; called by muse, varscan2
- TNRC6A | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100170417; called by muse, mutect2
- TRAPPC11 | c.3020T>A p.V1007E | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100592013; called by muse, mutect2, varscan2
- UBR1 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.879); catalogued as COSV99317752; called by muse, mutect2, varscan2
- USP28 | c.3179G>T p.R1060L | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777919556, COSV99136448; called by muse, mutect2, varscan2
- UTP25 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101504761; called by muse, mutect2, varscan2
- WDR11 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs369243512; called by muse, mutect2, varscan2
- WWP2 | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100598742; called by muse, mutect2, varscan2
- ZBTB3 | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101189002; called by muse, mutect2, varscan2
- ZC3H7A | c.1326G>C p.L442F | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100865597; called by muse, mutect2, varscan2
- ZFHX3 | c.6445C>T p.R2149C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51719804; called by muse, mutect2, varscan2
- ZNF182 | c.404G>C p.R135P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100527188, COSV59359735; called by muse, mutect2, varscan2
- ZNF208 | c.3797C>G p.S1266* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101237073, COSV101237186; called by muse, mutect2, varscan2
- ZNF221 | c.1058T>A p.L353H | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99240907; called by muse, mutect2, varscan2
- ZNF318 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 99/474 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV58933102; called by muse, mutect2, varscan2
- ZNF366 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs533088108, COSV59213941, COSV59215138; called by muse, mutect2, varscan2
- ZNF697 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV101360300; called by muse, mutect2
- DRD3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERCC6L2 | c.4001G>C p.R1334T | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HAS2 | c.1649_1650dup p.D551Lfs*69 | Frame Shift Ins (INS) | VAF 26/126 reads (21%) | called by mutect2, pindel
- HLA-A | c.896-17_915del p.X299_splice | Splice Site (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel
- PDS5B | c.3945C>G p.S1315R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRB2 | c.114C>T p.I38= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as COSV60005463; called by muse, mutect2, varscan2
- ASB8 | c.141G>C p.V47= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100402690; called by muse, mutect2
- ATP6V0A4 | c.1638C>T p.I546= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV59475843; called by muse, mutect2
- BACH2 | c.1626C>G p.L542= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs202242610, COSV100000761; called by muse, mutect2, varscan2
- CHI3L2 | c.618C>T p.F206= | Silent (SNP) | VAF 53/359 reads (15%) | catalogued as COSV100869320; called by muse, mutect2, varscan2
- CHST8 | c.316C>A p.R106= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99381552; called by muse, mutect2
- CSNK1E | c.267C>G p.L89= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs772756628, COSV100725089; called by muse, mutect2, varscan2
- DCUN1D3 | c.807C>G p.L269= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100177048; called by muse, mutect2, varscan2
- DGCR6L | c.168C>G p.L56= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99956927; called by muse, mutect2, varscan2
- FAM3A | c.390C>G p.V130= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100453690; called by muse, mutect2, varscan2
- HSPA1L | c.90C>T p.I30= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100989452; called by muse, mutect2
- IPO7 | c.2088C>T p.L696= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV101121843; called by muse, mutect2
- LPO | c.2052C>T p.F684= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs3744104, COSV51857699, COSV51863667; called by muse, mutect2, varscan2
- MARCHF11 | c.915T>A p.V305= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100198224; called by muse, mutect2, varscan2
- MARVELD2 | c.225C>G p.L75= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1198942007, COSV100347900; called by muse, mutect2, varscan2
- MCM3 | c.2424C>A p.V808= (on ENST00000229854 / NM_001366374.2; = p.V798= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/175 reads (7%) | catalogued as COSV100009024, COSV57718375; called by muse, mutect2
- MMP14 | c.1269C>T p.P423= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV100314297; called by muse, mutect2, varscan2
- MUC17 | c.1446G>A p.Q482= | Silent (SNP) | VAF 64/504 reads (13%) | catalogued as rs774759850, COSV100075334, COSV60296375; called by muse, mutect2, varscan2
- NPTX1 | c.1158G>A p.L386= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV100151164; called by muse, mutect2, varscan2
- OR2AE1 | c.231C>T p.I77= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100318377; called by muse, mutect2, varscan2
- PCP4L1 | c.105G>A p.E35= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV101552229; called by muse, mutect2
- RB1CC1 | c.2016A>T p.P672= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99212797; called by muse, mutect2, varscan2
- SH3TC2 | c.168C>T p.F56= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as COSV100102275; called by muse, mutect2, varscan2
- SLC12A1 | c.180C>T p.I60= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100372541; called by muse, mutect2, varscan2
- SLC27A2 | c.1287C>T p.I429= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV51057554; called by muse, mutect2, varscan2
- TFAP2D | c.1167G>A p.P389= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs149503577; called by muse, mutect2, varscan2
- TOGARAM2 | c.1119G>A p.R373= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV101091425; called by muse, mutect2, varscan2
- TP53I11 | c.507C>A p.L169= | Silent (SNP) | VAF 25/181 reads (14%) | catalogued as COSV100370976, COSV57534179; called by muse, mutect2, varscan2
- TSR1 | c.1620C>A p.I540= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100027190; called by muse, mutect2
- UBASH3A | c.1491C>G p.L497= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV52315977; called by muse, mutect2, varscan2
- USP31 | c.960C>T p.L320= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV99565769; called by muse, mutect2, varscan2
- ZNF354A | c.186G>A p.V62= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV59982986; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826927 A>T | 3'Flank (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- NRXN3 | c.602-5389G>A | Intron (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99816377; called by mutect2, varscan2
- SYTL2 | c.1459+3024G>A | Intron (SNP) | VAF 17/162 reads (10%) | catalogued as rs116798528, COSV60361120; called by muse, mutect2, varscan2
- TTN | c.34264+5561G>T | Intron (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100626892; called by muse, mutect2, varscan2
- TTN | c.10361-5067G>A | Intron (SNP) | VAF 39/199 reads (20%) | catalogued as COSV100626895, COSV60327461; called by muse, mutect2, varscan2
